Somatic mutation profile of tumor specimen C3L-09204-04 (aliquot CPT0499520006) from CPTAC case C3L-09204, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 81.8 years (29,868 days).
Specimen C3L-09204-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb34a60f-a338-4d95-820b-4ba8e0d0b213.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09204-31 (Blood Derived Normal), aliquot CPT0499640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57b0b049-5e1e-484f-9713-f7baaf8e258f

The open-access MAF lists 3,927 somatic variants for this specimen: 2,788 protein-altering or splice-affecting, 990 silent, 149 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,311, Silent 990, Frame Shift Del 275, Intron 83, Frame Shift Ins 72, Nonsense Mutation 70, 5'Flank 20, In Frame Del 19, 3'UTR 19, Splice Region 17, Splice Site 17, 5'UTR 12.

Variants (750 of 3,927; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.6792del p.A2265Pfs*72 | Frame Shift Del (DEL) | VAF 132/698 reads (19%) | catalogued as rs878855327; ClinVar: pathogenic; called by pindel, varscan2
- COL4A3 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs200672668, CM014042; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4400A>G p.Y1467C | Missense Mutation (SNP) | VAF 20/336 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54328389, COSV99607142, COSV99610059; called by muse, mutect2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 82/365 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FANCG | c.1158del p.S387Pfs*16 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs757418016; ClinVar: pathogenic; called by mutect2, pindel
- FOXG1 | c.460dup p.E154Gfs*301 | Frame Shift Ins (INS) | VAF 78/283 reads (28%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 26/214 reads (12%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KIF7 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 96/462 reads (21%) | catalogued as rs1235928535, CM113621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/319 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 51/294 reads (17%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MYL2 | c.431del p.P144Lfs*3 | Frame Shift Del (DEL) | VAF 54/250 reads (22%) | catalogued as rs786205430, CD130651; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- PCDH19 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 99/598 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052812, COSV55264382; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 64/344 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 52/241 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMPD1 | c.564del p.K189Nfs*68 | Frame Shift Del (DEL) | VAF 48/252 reads (19%) | catalogued as rs756366019; ClinVar: pathogenic; called by mutect2, pindel
- TRIO | c.3657dup p.C1220Mfs*7 | Frame Shift Ins (INS) | VAF 100/388 reads (26%) | catalogued as rs1554068529; ClinVar: likely pathogenic; called by mutect2, varscan2
- TUBA1A | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 143/592 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs137853043, CM074615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 144/302 reads (48%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA10 | c.4579G>A p.D1527N | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV52223647; called by muse, mutect2
- ABCA12 | c.6327dup p.G2110Wfs*3 (on ENST00000272895 / NM_173076.3; = p.G1792Wfs*3 on NM_015657.3) | Frame Shift Ins (INS) | VAF 36/290 reads (12%) | catalogued as rs1204636023; called by mutect2, varscan2
- ABCA2 | c.1592G>A p.R531H (on ENST00000614293; = p.R501H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.157); catalogued as rs763695096; called by muse, mutect2, varscan2
- ABCA6 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs377306226; called by muse, mutect2, varscan2
- ABCC12 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 36/447 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as rs771754129; called by muse, mutect2
- ABCC8 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 21/483 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as CM073986; called by muse, mutect2
- ABCG1 | c.1076del p.G359Vfs*5 | Frame Shift Del (DEL) | VAF 100/412 reads (24%) | catalogued as rs1569239566, CM138401; called by mutect2, varscan2
- ABI1 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61018684; called by muse, mutect2, varscan2
- AC105001.2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 69/565 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs373290895; called by muse, mutect2, varscan2
- ACADS | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 28/503 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs1219162519; called by muse, mutect2
- ACIN1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs768644124; called by muse, mutect2, varscan2
- ACP2 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.269); catalogued as rs865928928, COSV99922177; called by muse, varscan2
- ACSBG2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs940495531, COSV53124229; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 124/246 reads (50%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs202049961; called by muse, mutect2, varscan2
- ADAM2 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 87/552 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs907635766, COSV55863839; called by muse, mutect2, varscan2
- ADAMTS1 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 97/453 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs200821463, COSV53171170; called by muse, mutect2, varscan2
- ADAMTS1 | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 42/557 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53172319; called by muse, mutect2
- ADAMTS10 | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.943); catalogued as rs373603462; called by muse, mutect2, varscan2
- ADAMTS13 | c.3683G>A p.R1228H | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs781945456; called by muse, mutect2, varscan2
- ADCY1 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as rs368928291; called by muse, varscan2
- ADD3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376844168; called by muse, mutect2, varscan2
- ADGRA2 | c.2516G>A p.G839D | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1305775305, COSV55105072; called by muse, mutect2
- ADGRA3 | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 77/410 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370767567, COSV51560464; called by muse, mutect2, varscan2
- ADGRL4 | c.1985del p.L662Yfs*28 | Frame Shift Del (DEL) | VAF 58/309 reads (19%) | catalogued as rs770040543; called by mutect2, pindel, varscan2
- ADGRV1 | c.4201A>G p.K1401E | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs1328724199; called by muse, mutect2
- ADGRV1 | c.8699C>T p.T2900I | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251785955; called by muse, mutect2
- ADM5 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 132/592 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.796); catalogued as rs1206962186; called by muse, varscan2
- ADNP2 | c.2908C>T p.H970Y | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.466); catalogued as COSV51540136; called by muse, mutect2, varscan2
- AGBL1 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 21/388 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV66863024; called by muse, mutect2
- AGO2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 98/536 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55046834; called by muse, varscan2
- AGO2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 85/510 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV55046684; called by muse, mutect2, varscan2
- AHNAK | c.15769G>A p.A5257T | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV57203620; called by muse, mutect2
- AHNAK2 | c.11562G>T p.Q3854H | Missense Mutation (SNP) | VAF 113/492 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs771396721; called by muse, mutect2, varscan2
- AHNAK2 | c.3442del p.E1148Nfs*9 | Frame Shift Del (DEL) | VAF 105/462 reads (23%) | catalogued as rs1282120199; called by mutect2, pindel, varscan2
- AK7 | c.452T>C p.L151S | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1430352254, COSV50873042; called by muse, mutect2
- AKAP11 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs1388070458; called by muse, mutect2, varscan2
- AKAP6 | c.5258G>A p.S1753N | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1225291138; called by muse, mutect2, varscan2
- AKAP9 | c.9179A>G p.E3060G (on ENST00000359028; = p.E3036G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV62350854; called by muse, mutect2
- AKR1C3 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as rs138882693; called by muse, mutect2, varscan2
- AKT2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as rs1017033490, COSV60907814; called by muse, mutect2, varscan2
- AL354761.1 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.61); catalogued as rs563647936; called by muse, mutect2, varscan2
- ALKAL1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 65/579 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.14); catalogued as rs577185547; called by muse, mutect2, varscan2
- ALMS1 | c.3659C>A p.P1220H | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV100042064; called by muse, mutect2, varscan2
- ALOXE3 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 98/421 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs750553644; called by muse, mutect2, varscan2
- ALPK3 | c.2858A>G p.D953G | Missense Mutation (SNP) | VAF 35/575 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51941444; called by muse, mutect2
- ALPK3 | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs760060304, COSV51938505; called by muse, mutect2, varscan2
- AMER1 | c.2566A>G p.S856G | Missense Mutation (SNP) | VAF 42/518 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs778363299, COSV100366345; called by muse, mutect2
- AMPD1 | c.2045A>G p.D682G | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475553694; called by muse, mutect2, varscan2
- ANK1 | c.3547G>A p.A1183T | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs763277980; called by muse, mutect2, varscan2
- ANKRD12 | c.4955T>C p.L1652S | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs1024239206; called by muse, mutect2
- ANKRD17 | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs528309707; called by muse, mutect2, varscan2
- ANKRD27 | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 110/411 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs145648811; called by muse, mutect2, varscan2
- ANKRD62 | c.1439dup p.L481Afs*3 | Frame Shift Ins (INS) | VAF 37/183 reads (20%) | catalogued as rs774510795; called by mutect2, varscan2
- ANXA9 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV64485001; called by muse, mutect2, varscan2
- APOA5 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 105/440 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs867592586; called by muse, mutect2, varscan2
- APOBEC1 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.965); catalogued as COSV99981026; called by muse, mutect2, varscan2
- APOBEC3B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766117548, COSV59841046; called by muse, mutect2, varscan2
- APOE | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 121/472 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749406635; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 32/216 reads (15%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP3 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 54/686 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs749564614; called by muse, mutect2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 52/170 reads (31%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARFGAP3 | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs757780559; called by muse, mutect2, varscan2
- ARFGEF3 | c.6173G>A p.G2058D | Missense Mutation (SNP) | VAF 74/555 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs751361379; called by muse, mutect2, varscan2
- ARFIP2 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54448028; called by muse, varscan2
- ARHGAP21 | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 54/248 reads (22%) | catalogued as rs149363020; called by muse, varscan2
- ARHGAP32 | c.4934G>A p.R1645Q (on ENST00000310343 / NM_001378025.1; = p.R1296Q on NM_014715.4) | Missense Mutation (SNP) | VAF 68/440 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758198053, COSV100088532; called by muse, mutect2, varscan2
- ARHGAP45 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 109/518 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV100490630; called by muse, mutect2, varscan2
- ARHGAP45 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 43/531 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1212400408; called by muse, mutect2
- ARHGEF10L | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs1211843080; called by muse, mutect2
- ARHGEF33 | c.1435T>C p.S479P | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); catalogued as rs1357232199, COSV101289804; called by muse, mutect2, varscan2
- ARID1A | c.5506G>T p.E1836* | Nonsense Mutation (SNP) | VAF 102/480 reads (21%) | catalogued as COSV61375534; called by muse, varscan2
- ARID1A | c.5549A>G p.D1850G | Missense Mutation (SNP) | VAF 81/498 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs750044693, COSV61384663; called by muse, varscan2
- ARID1B | c.5701C>T p.R1901W | Missense Mutation (SNP) | VAF 94/537 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs530153456; called by muse, mutect2, varscan2
- ARL4A | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.124); catalogued as rs761190669; called by muse, mutect2, varscan2
- ARL5C | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as rs954948233; called by muse, mutect2
- ARNTL2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 75/365 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764381779; called by muse, mutect2, varscan2
- ASAP1 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63054834; called by muse, mutect2
- ASB12 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 75/479 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs752937556, COSV100744703; called by muse, mutect2, varscan2
- ASCL5 | c.447del p.A150Lfs*69 | Frame Shift Del (DEL) | VAF 69/486 reads (14%) | catalogued as rs1184004486; called by mutect2, pindel, varscan2
- ASH1L | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs374072309; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 84/393 reads (21%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATF7 | c.1036C>T p.R346W (on ENST00000548446 / NM_001366555.2; = p.R335W on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129388; called by muse, mutect2, varscan2
- ATG2A | c.5504C>T p.A1835V | Missense Mutation (SNP) | VAF 161/669 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs370496305; called by muse, mutect2, varscan2
- ATG2B | c.6046G>A p.A2016T | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.152); catalogued as rs1456141131, COSV99951964; called by muse, mutect2
- ATG9B | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.274); catalogued as rs769664369; called by muse, mutect2, varscan2
- ATP11C | c.71_72del p.T24Sfs*21 | Frame Shift Del (DEL) | VAF 26/180 reads (14%) | catalogued as rs1224866423; called by pindel, varscan2
- ATP13A1 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs769521754, COSV99179316; called by muse, mutect2, varscan2
- ATP1A1 | c.1640del p.G547Afs*7 | Frame Shift Del (DEL) | VAF 46/361 reads (13%) | catalogued as rs760784617; called by mutect2, pindel, varscan2
- ATP1B2 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.985); catalogued as rs1247152743; called by muse, mutect2
- ATP2C1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs756074470, COSV60758511; called by muse, mutect2, varscan2
- ATP8B4 | c.2319T>G p.N773K | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV52717095; called by muse, mutect2, varscan2
- ATR | c.2149A>G p.T717A | Missense Mutation (SNP) | VAF 29/369 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1249892072; called by muse, mutect2
- ATRX | c.3238A>G p.K1080E | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.265); catalogued as COSV64872241; called by muse, mutect2
- ATXN2 | c.2168C>A p.P723H (on ENST00000550104; = p.P563H on NM_002973.4) | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as rs1428315521; called by muse, mutect2, varscan2
- AVIL | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs147036496; called by muse, mutect2, varscan2
- AVL9 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs759557265, COSV59464560; called by muse, mutect2, varscan2
- B3GALT4 | c.725del p.G242Afs*48 | Frame Shift Del (DEL) | VAF 154/806 reads (19%) | catalogued as rs779828300; called by mutect2, pindel, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, mutect2, varscan2
- BCAM | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.228); catalogued as COSV99539036; called by muse, mutect2, varscan2
- BCL2 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 48/768 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as rs1448547701, COSV61375355, COSV61379913, COSV61385356; called by muse, mutect2
- BCLAF1 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 39/211 reads (18%) | catalogued as rs138333275, CM136163; called by muse, mutect2, varscan2
- BCOR | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 94/529 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as rs754579483, COSV60721138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICDL1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs771000745; called by muse, mutect2, varscan2
- BLMH | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 18/363 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913131; called by muse, mutect2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 70/314 reads (22%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOC | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750791560; called by muse, mutect2, varscan2
- BORCS6 | c.766del p.I256Sfs*12 | Frame Shift Del (DEL) | VAF 158/725 reads (22%) | catalogued as rs751878342; called by mutect2, pindel, varscan2
- BRAT1 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs755296109, COSV61396051; called by muse, varscan2
- BRD3 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 93/440 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs200271220; called by muse, mutect2, varscan2
- BRINP1 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 81/474 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs370571795; called by muse, mutect2, varscan2
- BRSK2 | c.1063dup p.R355Pfs*48 | Frame Shift Ins (INS) | VAF 66/314 reads (21%) | catalogued as rs779380593; called by mutect2, varscan2
- BTNL2 | c.1310T>C p.I437T | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs955895092; called by muse, mutect2, varscan2
- C12orf66 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV61323549; called by muse, mutect2, varscan2
- C1orf127 | c.2359del p.A787Pfs*7 | Frame Shift Del (DEL) | VAF 65/474 reads (14%) | catalogued as rs1283160262; called by mutect2, pindel, varscan2
- C2CD4C | c.162dup p.K55Qfs*73 | Frame Shift Ins (INS) | VAF 136/605 reads (22%) | catalogued as rs781343562; called by mutect2, varscan2
- C4B | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 129/633 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs2229403; called by muse, mutect2, varscan2
- CA9 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV61404817; called by muse, mutect2
- CABP2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs765901779; called by muse, mutect2, varscan2
- CACNA1A | c.6449C>T p.P2150L | Missense Mutation (SNP) | VAF 138/601 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs750077868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.3004G>A p.G1002R | Missense Mutation (SNP) | VAF 209/785 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as rs781006387; called by muse, mutect2, varscan2
- CACNA1E | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs370013304, COSV62390334; called by muse, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 38/239 reads (16%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CAMSAP1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs983805795, COSV56719948; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 57/331 reads (17%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMSAP3 | c.2933C>T p.T978M | Missense Mutation (SNP) | VAF 65/743 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454756784, COSV50331408; called by muse, mutect2
- CAPN15 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.186); catalogued as rs1368981013; called by muse, mutect2
- CAPN15 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 112/597 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762523863; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/272 reads (20%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASP9 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1268749727, COSV100423871; called by muse, mutect2
- CBLB | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.484); catalogued as rs765424819; called by muse, varscan2
- CBX6 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 136/657 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99328219; called by muse, mutect2, varscan2
- CC2D2A | c.1622A>G p.Q541R | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs764371197; called by muse, mutect2, varscan2
- CCDC142 | c.1658T>C p.V553A (on ENST00000393965 / NM_001365575.2; = p.V546A on NM_032779.4) | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.176); catalogued as rs1230849800; called by muse, mutect2
- CCDC150 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99776799; called by muse, mutect2
- CCDC168 | c.9268A>G p.T3090A | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as rs1165402801; called by muse, mutect2
- CCDC168 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs373477538; called by muse, mutect2, varscan2
- CCDC27 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs765415352, COSV53900576; called by muse, mutect2
- CCDC51 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 38/656 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1297388218; called by muse, mutect2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 30/147 reads (20%) | catalogued as rs747079826; called by mutect2, varscan2
- CCN4 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 111/621 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs529938783, COSV51533599; called by muse, mutect2, varscan2
- CCR10 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 198/696 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs1349412503; called by muse, mutect2, varscan2
- CCR7 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1197360636; called by muse, mutect2
- CD163L1 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs756556844; called by muse, mutect2, varscan2
- CD37 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 97/494 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs1222367490; called by muse, mutect2, varscan2
- CDC40 | c.1501A>T p.I501F | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV57009841; called by muse, mutect2, varscan2
- CDH22 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs144000272; called by muse, mutect2, varscan2
- CDH23 | c.4891G>A p.A1631T | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs780170048, COSV56466142; called by muse, mutect2, varscan2
- CDH4 | c.2004C>T p.N668= | Splice Region (SNP) | VAF 76/301 reads (25%) | catalogued as rs199501765; called by muse, mutect2, varscan2
- CDK12 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs143648695, COSV71002912; called by muse, mutect2
- CDK5 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.245); catalogued as rs1263825861; called by muse, mutect2, varscan2
- CDK9 | c.627del p.I210Lfs*66 | Frame Shift Del (DEL) | VAF 64/419 reads (15%) | catalogued as rs755440676; called by mutect2, pindel, varscan2
- CELSR1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 68/518 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.157); catalogued as rs1360607220; called by muse, mutect2, varscan2
- CENPJ | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753604037, COSV55041334; called by muse, varscan2
- CENPS-CORT | c.485_487del p.S162del | In Frame Del (DEL) | VAF 54/258 reads (21%) | catalogued as rs772618348; called by pindel, varscan2
- CEP170 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs772474355, COSV100839864; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP63 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs765783970; called by muse, mutect2, varscan2
- CFAP251 | c.2177A>G p.N726S | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs746010935; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 26/143 reads (18%) | catalogued as rs1274191949; called by mutect2, varscan2
- CFAP58 | c.1407G>T p.Q469H | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100866181, COSV63835658; called by muse, mutect2, varscan2
- CFAP92 | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.388); catalogued as rs149770595; called by muse, mutect2, varscan2
- CHCHD3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs201557228; called by muse, varscan2
- CHD3 | c.5998G>A p.D2000N (on ENST00000330494 / NM_001005273.3; = p.D1966N on NM_005852.4) | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1306527244; called by muse, mutect2, varscan2
- CHD4 | c.4249C>T p.R1417* (on ENST00000357008 / NM_001363606.2; = p.R1430* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 106/414 reads (26%) | catalogued as COSV58895634; called by muse, mutect2, varscan2
- CHD4 | c.3292C>T p.R1098C (on ENST00000357008 / NM_001363606.2; = p.R1111C on NM_001273.5) | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58909231; called by muse, mutect2, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 34/311 reads (11%) | catalogued as rs748826986; called by mutect2, varscan2
- CHRNA2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs968471265; called by muse, mutect2
- CIBAR1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as rs559199944, COSV63897957; called by muse, mutect2, varscan2
- CIC | c.3829C>T p.R1277C | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs587778206, COSV50554305; ClinVar: not provided; called by muse, varscan2
- CIZ1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752977398; called by muse, mutect2, varscan2
- CKAP5 | c.2140T>C p.W714R | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs911465730; called by muse, mutect2, varscan2
- CLDN6 | c.567dup p.S190Vfs*24 | Frame Shift Ins (INS) | VAF 84/398 reads (21%) | catalogued as rs756736939; called by mutect2, varscan2
- CLEC17A | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV60426716; called by muse, mutect2, varscan2
- CLEC3A | c.397G>A p.G133S (on ENST00000651443; = p.G124S on NM_005752.6) | Missense Mutation (SNP) | VAF 21/492 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as rs866218755, COSV100222158, COSV55219791; called by muse, mutect2
- CLIC1 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 26/513 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs747988662; called by muse, mutect2
- CLIP3 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs146745838; called by muse, mutect2, varscan2
- CLSPN | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 39/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs751005466, COSV52052599; called by muse, mutect2, varscan2
- CMTM5 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs147365003; called by muse, mutect2, varscan2
- CMYA5 | c.8045C>T p.S2682L | Missense Mutation (SNP) | VAF 99/434 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs764600304, COSV71404527; called by muse, mutect2, varscan2
- CNDP1 | c.1142T>C p.M381T | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100722363; called by muse, mutect2, varscan2
- CNOT3 | c.1931C>A p.P644Q | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55361113; called by muse, mutect2, varscan2
- CNTLN | c.2485A>G p.K829E | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99265182; called by muse, mutect2
- CNTNAP1 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs1265482613; called by muse, varscan2
- COL1A2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 63/372 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs775489170; called by muse, mutect2, varscan2
- COL6A1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201213605, COSV62613526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.2481del p.K827Nfs*7 | Frame Shift Del (DEL) | VAF 70/361 reads (19%) | catalogued as rs1222064379; called by mutect2, pindel, varscan2
- COL6A6 | c.*5del | Frame Shift Del (DEL) | VAF 55/214 reads (26%) | catalogued as rs747090655; called by mutect2, pindel, varscan2
- COL7A1 | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 141/496 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238130301; called by muse, mutect2, varscan2
- CORO1B | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 21/524 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV58171408; called by muse, mutect2
- CORO2B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230243277; called by muse, mutect2, varscan2
- CPN2 | c.701del p.P234Lfs*10 | Frame Shift Del (DEL) | VAF 113/565 reads (20%) | catalogued as COSV100103034; called by mutect2, pindel, varscan2
- CPNE9 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746351427; called by muse, mutect2, varscan2
- CPSF1 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 105/686 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs923716907, COSV58233661; called by muse, mutect2, varscan2
- CPSF1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 38/794 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs782187045; called by muse, mutect2
- CPSF6 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1479950749, COSV99879310; called by muse, mutect2, varscan2
- CPZ | c.293G>A p.R98Q (on ENST00000360986 / NM_001014447.3; = p.R87Q on NM_003652.3) | Missense Mutation (SNP) | VAF 148/608 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781743967; called by muse, varscan2
- CRACDL | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs767437682, COSV67407180; called by muse, mutect2, varscan2
- CRB2 | c.1786G>A p.G596S | Missense Mutation (SNP) | VAF 33/646 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1218300959; called by muse, mutect2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 45/282 reads (16%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRTAC1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs772062581, COSV53997647; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 60/240 reads (25%) | catalogued as rs769538822; called by mutect2, varscan2
- CRY2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 53/508 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769770457, COSV101314596, COSV101314610; called by muse, mutect2, varscan2
- CRYBG1 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs775714727, COSV64813754; called by muse, mutect2, varscan2
- CSMD1 | c.1510C>T p.H504Y (on ENST00000520002; = p.H503Y on NM_033225.6) | Missense Mutation (SNP) | VAF 45/303 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.403); catalogued as rs745959484, COSV68179386; called by muse, mutect2, varscan2
- CSNK1E | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs373100204; called by muse, mutect2, varscan2
- CSRP3 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 88/473 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777211110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1162734122; called by muse, mutect2
- CTNNB1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 68/451 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs771596917, COSV62703866; called by muse, mutect2, varscan2
- CTPS2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs371894543; called by muse, mutect2, varscan2
- CUL7 | c.5072C>T p.T1691I | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs140092102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX1 | c.3820A>G p.I1274V | Missense Mutation (SNP) | VAF 21/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368394580; called by muse, mutect2
- CUX1 | c.1681G>A p.G561S (on ENST00000437600 / NM_181500.4; = p.G563S on NM_001913.5) | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs187131238; called by muse, mutect2, varscan2
- CUX2 | c.4104G>T p.E1368D | Missense Mutation (SNP) | VAF 69/517 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV55626406; called by muse, mutect2, varscan2
- CYHR1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 47/632 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV71324675; called by muse, mutect2
- CYLC1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 33/371 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100253896, COSV61412186; called by muse, mutect2
- CYP11B1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 34/774 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV52825230; called by muse, mutect2
- CYP26C1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 102/474 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99592009; called by muse, mutect2, varscan2
- CYP2A6 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 74/638 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); catalogued as rs1465959396, COSV99991835; called by muse, mutect2, varscan2
- CYP3A7 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 38/393 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs1229908716, COSV100312777; called by muse, mutect2, varscan2
- CYP7A1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.383); catalogued as rs1168837944, COSV100052202; called by muse, mutect2
- DAAM1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 87/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759856885, CM154571, COSV100658513; called by muse, mutect2, varscan2
- DACT2 | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 34/718 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs1367058008, COSV64693806; called by muse, mutect2
- DACT2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs1437213801; called by muse, mutect2
- DAGLA | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV57194108; called by muse, mutect2, varscan2
- DBX2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 138/615 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs760536409, COSV60337045; called by muse, varscan2
- DCAF12L1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 113/590 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV64421734, COSV64422590; called by muse, mutect2, varscan2
- DCAF12L1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 102/513 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.208); catalogued as COSV100948498; called by muse, mutect2, varscan2
- DCAF12L2 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 109/457 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1254668948, COSV63583106; called by mutect2, varscan2
- DCAF4L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 33/399 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV60788486; called by muse, mutect2
- DCHS1 | c.4588G>A p.V1530I | Missense Mutation (SNP) | VAF 126/599 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs963037578; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 30/594 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2
- DCTN1 | c.2754del p.S919Afs*25 | Frame Shift Del (DEL) | VAF 31/269 reads (12%) | catalogued as rs1229620804; called by mutect2, pindel, varscan2
- DDX5 | c.1565T>C p.L522P | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV56751767; called by muse, mutect2
- DDX50 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1429017781; called by muse, mutect2
- DEFB132 | c.127del p.E43Rfs*51 | Frame Shift Del (DEL) | VAF 66/356 reads (19%) | catalogued as rs776618282; called by mutect2, varscan2
- DENND3 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 100/610 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs773494985; called by muse, mutect2, varscan2
- DEPTOR | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99639763; called by muse, mutect2
- DES | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 128/471 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs1057524813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGCR6L | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 127/474 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs1401265177; called by muse, mutect2, varscan2
- DGKE | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 42/621 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as rs775804689; called by muse, mutect2
- DHRSX | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.39); catalogued as rs759302112; called by muse, mutect2, varscan2
- DHX30 | c.1352C>T p.P451L (on ENST00000445061 / NM_138615.3; = p.P412L on NM_014966.3) | Missense Mutation (SNP) | VAF 106/495 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.594); catalogued as rs368673690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX8 | c.3156G>A p.W1052* | Nonsense Mutation (SNP) | VAF 17/457 reads (4%) | catalogued as rs1458293331; called by muse, mutect2
- DIO2 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 83/391 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70444970, COSV70445363; called by muse, mutect2, varscan2
- DKK4 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs529642073; called by muse, mutect2, varscan2
- DLG5 | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs748990884, COSV64949946; called by muse, mutect2, varscan2
- DLX2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 152/615 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1325103506; called by muse, mutect2, varscan2
- DMD | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as CD100291, CM098350; called by muse, mutect2
- DMRTA2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 26/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1468546155; called by muse, mutect2
- DNAH17 | c.13106G>A p.R4369Q | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs771274028; called by muse, mutect2, varscan2
- DNAH2 | c.3676-1G>T p.X1226_splice | Splice Site (SNP) | VAF 28/323 reads (9%) | catalogued as COSV66721397; called by muse, mutect2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 56/282 reads (20%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNHD1 | c.7669C>T p.R2557C | Missense Mutation (SNP) | VAF 94/471 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs901692242; called by muse, mutect2, varscan2
- DNMT1 | c.4372A>G p.T1458A | Missense Mutation (SNP) | VAF 47/596 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs750520436; called by muse, mutect2
- DNMT1 | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs767421908, COSV61577175; called by muse, mutect2, varscan2
- DNMT1 | c.3049C>T p.R1017W | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs144533539; called by muse, mutect2, varscan2
- DNMT3A | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs1326972729, COSV53051524; called by muse, mutect2, varscan2
- DOCK2 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912354; called by muse, mutect2, varscan2
- DOCK4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs200422451, COSV101455492; called by muse, mutect2, varscan2
- DOT1L | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs376751030; called by muse, varscan2
- DPRX | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as rs1470420637, COSV64949722; called by muse, mutect2, varscan2
- DROSHA | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60772442, COSV60774126; called by muse, mutect2, varscan2
- DUOXA2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV50993027; called by muse, mutect2, varscan2
- DYNC1H1 | c.3686A>G p.D1229G | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as COSV64138512; called by muse, mutect2
- DYNC2H1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as rs747976646, COSV100519354; called by muse, mutect2, varscan2
- DYNC2H1 | c.8215T>C p.Y2739H | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1285875834; called by muse, mutect2
- DYRK1B | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 85/432 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs966556487, COSV99695438; called by muse, mutect2, varscan2
- EDRF1 | c.1342T>A p.Y448N (on ENST00000356792 / NM_001202438.2; = p.Y414N on NM_015608.2) | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.341); catalogued as COSV100523450; called by muse, mutect2
- EDRF1 | c.2635del p.S879Afs*46 (on ENST00000356792 / NM_001202438.2; = p.S845Afs*46 on NM_015608.2) | Frame Shift Del (DEL) | VAF 76/314 reads (24%) | catalogued as rs1388716596, COSV100523284; called by pindel, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 65/347 reads (19%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EIF2AK2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs770329106; called by muse, mutect2, varscan2
- EIF3A | c.795del p.K265Nfs*7 | Frame Shift Del (DEL) | VAF 33/370 reads (9%) | catalogued as rs34481774; called by mutect2, pindel
- EIF3C | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 59/1280 reads (5%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.509); catalogued as rs1203860641; called by muse, mutect2
- EIF3H | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1246648329, COSV52673106; called by muse, mutect2, varscan2
- EIPR1 | c.947A>C p.D316A | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV66130058; called by muse, mutect2
- ELAC2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs1382116568, CM012929, COSV100568342; called by muse, mutect2
- ELAVL1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs780607258, COSV60966397; called by muse, mutect2, varscan2
- ELFN1 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 63/598 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs756943282; called by muse, mutect2, varscan2
- ELFN1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 109/654 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1350475033; called by muse, varscan2
- ELMO1 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs781018207; called by muse, mutect2, varscan2
- ELOA2 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 102/452 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs549369877; called by muse, mutect2, varscan2
- ELOVL1 | c.122T>C p.F41S | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV60523067; called by muse, mutect2
- EML2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs547785842; called by muse, varscan2
- EN2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 123/431 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs537483172, COSV52082956; called by muse, mutect2, varscan2
- ENO3 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs201499925; called by muse, mutect2, varscan2
- ENTPD2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 103/551 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs759351054, COSV100445722, COSV57074399; called by muse, mutect2, varscan2
- EOMES | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 23/732 reads (3%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV99842044; called by muse, mutect2
- EP400 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 52/674 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.013); catalogued as COSV57771695; called by muse, mutect2
- EPB41L3 | c.876dup p.L293Ifs*12 | Frame Shift Ins (INS) | VAF 46/273 reads (17%) | catalogued as rs1484979313; called by mutect2, pindel, varscan2
- EPHA3 | c.1963C>A p.L655M | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60692332; called by muse, mutect2
- EPN1 | c.905C>T p.P302L (on ENST00000270460 / NM_001321263.1; = p.P277L on NM_013333.3) | Missense Mutation (SNP) | VAF 187/746 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs375948547; called by muse, mutect2, varscan2
- EPS8L1 | c.2021C>T p.A674V (on ENST00000201647 / NM_133180.3; = p.A547V on NM_017729.3) | Missense Mutation (SNP) | VAF 38/610 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs995815801, COSV52381827; called by muse, mutect2
- EPS8L3 | c.1378G>A p.E460K (on ENST00000361965 / NM_133181.4; = p.E430K on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/441 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs762702784, COSV62608877; called by muse, mutect2, varscan2
- ERBB2 | c.3041T>C p.M1014T | Missense Mutation (SNP) | VAF 31/523 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99508373; called by muse, mutect2
- ERCC4 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs766395322, COSV61311320; called by muse, mutect2, varscan2
- ERGIC3 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54136451; called by muse, mutect2, varscan2
- ESR1 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 44/704 reads (6%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.87); catalogued as COSV99237955; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 88/447 reads (20%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI5L | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 95/380 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs752791877, COSV54487674; called by muse, mutect2, varscan2
- EXO1 | c.135del p.K45Nfs*2 | Frame Shift Del (DEL) | VAF 34/230 reads (15%) | catalogued as rs1160395613; called by mutect2, pindel, varscan2
- EXO1 | c.1522dup p.C508Lfs*7 | Frame Shift Ins (INS) | VAF 24/179 reads (13%) | catalogued as rs763386152; called by mutect2, varscan2
- EYA1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.675); catalogued as COSV100378341; called by muse, mutect2, varscan2
- F2 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs200934494; called by muse, mutect2, varscan2
- FAM184B | c.1574A>G p.H525R | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs970377413; called by muse, mutect2, varscan2
- FAM189A1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 111/525 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs760154362, COSV99723233; called by muse, mutect2, varscan2
- FAM214A | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as rs369015694; called by muse, mutect2, varscan2
- FAM43A | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 144/665 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61673294; called by muse, mutect2, varscan2
- FAM83H | c.694T>C p.F232L | Missense Mutation (SNP) | VAF 40/701 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474320266; called by muse, mutect2
- FAT1 | c.6508G>A p.V2170I | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as rs377169844; called by muse, mutect2, varscan2
- FAT1 | c.3745T>C p.F1249L | Missense Mutation (SNP) | VAF 36/506 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as COSV71675684; called by muse, mutect2
- FAT3 | c.8786A>G p.Y2929C | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs773636509; called by muse, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 56/230 reads (24%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO32 | c.430A>T p.N144Y | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV99785852; called by muse, mutect2
- FBXO42 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 81/479 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as rs1057483349; called by muse, varscan2
- FCHO2 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99821979; called by muse, mutect2, varscan2
- FCRL5 | c.198A>G p.I66M | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs1220992636; called by muse, mutect2
- FES | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 110/513 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs779391057; called by muse, mutect2, varscan2
- FEZF1 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 61/517 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100484536; called by muse, mutect2, varscan2
- FGF18 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs781557133; called by muse, mutect2, varscan2
- FLG | c.4828C>T p.R1610W | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs560805546, COSV64238918; called by muse, mutect2, varscan2
- FLNA | c.3707G>A p.G1236D | Missense Mutation (SNP) | VAF 144/520 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV61049681; called by muse, mutect2, varscan2
- FLNB | c.6073G>A p.V2025M | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774677814, COSV55877028; called by muse, mutect2, varscan2
- FMO1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 66/332 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.099); catalogued as rs765073901, COSV61445185; called by muse, mutect2, varscan2
- FN1 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1330722076; called by muse, mutect2, varscan2
- FOCAD | c.2543G>A p.S848N | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1323802242; called by muse, mutect2
- FOCAD | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs766708794; called by muse, varscan2
- FOXC2 | c.1479del p.Y494Tfs*60 | Frame Shift Del (DEL) | VAF 58/437 reads (13%) | catalogued as CM126128; called by mutect2, pindel, varscan2
- FOXD4L6 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as rs1340827419; called by mutect2, varscan2
- FOXO3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 68/473 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182293435; called by muse, mutect2, varscan2
- FREM2 | c.3751A>G p.S1251G | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1384764798, COSV54834770, COSV54840611; called by muse, mutect2
- FRMD4A | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.481); catalogued as rs1490827324, COSV52724611; called by muse, mutect2, varscan2
- FRMPD3 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs753741770, COSV52197609; called by muse, mutect2, varscan2
- FRYL | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 107/413 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.131); catalogued as rs754986017, COSV51950664; called by muse, mutect2, varscan2
- FSCB | c.1141_1143del p.L381del | In Frame Del (DEL) | VAF 78/365 reads (21%) | catalogued as rs1208854888; called by pindel, varscan2
- FSTL1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs879101555, COSV55232250; called by muse, mutect2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 71/383 reads (19%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FUT11 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 85/510 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as rs1235067667, COSV59541587; called by muse, mutect2, varscan2
- FUT3 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 147/607 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1176415830; called by muse, mutect2, varscan2
- FXN | c.257G>T p.S86I (on ENST00000377270; = p.S161I on NM_000144.5) | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66010483; called by muse, mutect2, varscan2
- FYCO1 | c.4235C>T p.P1412L | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs376786114, COSV56116203; called by muse, mutect2, varscan2
- FZD5 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 130/538 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1430749048; called by muse, mutect2, varscan2
- GABPA | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV61395755; called by muse, mutect2, varscan2
- GALNT12 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200112438; called by muse, mutect2, varscan2
- GALNT7 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.88); catalogued as COSV53930611; called by muse, mutect2
- GAMT | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 93/424 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1028432497; called by muse, mutect2, varscan2
- GAREM1 | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 99/364 reads (27%) | catalogued as rs778300861; called by muse, mutect2, varscan2
- GCM1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs138196931; called by muse, mutect2, varscan2
- GCM2 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 47/437 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs958487240; called by muse, mutect2, varscan2
- GFPT2 | c.2004+1G>A p.X668_splice | Splice Site (SNP) | VAF 70/206 reads (34%) | catalogued as rs745564182; called by muse, varscan2
- GFY | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 133/547 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV99676813; called by muse, mutect2, varscan2
- GIMAP2 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 25/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56236284; called by muse, mutect2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 85/417 reads (20%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GJA8 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 33/547 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs917690151, COSV53789436; ClinVar: uncertain significance; called by muse, mutect2
- GK2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV62626715; called by muse, mutect2, varscan2
- GLI2 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs148317983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI2 | c.2033C>T p.T678M (on ENST00000361492 / NM_001374353.1; = p.T695M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/574 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150858529, COSV58042900; called by muse, mutect2, varscan2
- GLIS2 | c.1373T>C p.M458T | Missense Mutation (SNP) | VAF 45/767 reads (6%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs748007729; called by muse, mutect2
- GLT8D2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1446052188; called by muse, mutect2
- GML | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs199525495, COSV99638031; called by muse, mutect2, varscan2
- GNA13 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 82/397 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228101570, COSV71474881; called by muse, mutect2, varscan2
- GNA13 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV71475318; called by muse, mutect2
- GNB3 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 25/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375004756; called by muse, mutect2
- GOLGA3 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 75/258 reads (29%) | catalogued as rs1440872614; called by muse, mutect2, varscan2
- GOLGA6L10 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.249); catalogued as rs1303508997; called by muse, mutect2, varscan2
- GOLGB1 | c.8344_8345dup p.D2782Efs*12 | Frame Shift Ins (INS) | VAF 51/340 reads (15%) | catalogued as rs747719358; called by mutect2, varscan2
- GON4L | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV99675248; called by muse, mutect2
- GP1BA | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 24/603 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD942323; called by muse, mutect2
- GPATCH8 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 116/510 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV59196509; called by muse, mutect2, varscan2
- GPR143 | c.1175A>T p.N392I | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.118); catalogued as rs772902759; called by muse, mutect2, varscan2
- GPR148 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 119/524 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs746616372; called by muse, mutect2, varscan2
- GPR158 | c.3472A>T p.S1158C | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV66269337; called by muse, mutect2
- GPR26 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs369185135; called by muse, mutect2, varscan2
- GPR68 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 32/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53177574; called by muse, mutect2
- GPX6 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100724934; called by muse, mutect2, varscan2
- GRB14 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs138078116, COSV55736441; called by muse, mutect2, varscan2
- GREB1L | c.4284A>G p.I1428M | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs887912382; called by muse, mutect2
- GRIK1 | c.2755dup p.I919Nfs*8 (on ENST00000327783 / NM_001330994.2; = p.I875Nfs*8 on NM_175611.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 52/254 reads (20%) | catalogued as rs1200907182; called by mutect2, varscan2
- GRIN1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 122/478 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs199593246; called by muse, mutect2, varscan2
- GRIN3A | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100701881; called by muse, mutect2
- GRM4 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1301629622, COSV65221742; called by muse, mutect2
- GSE1 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 28/670 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1365620212; called by muse, mutect2
- GTF2H2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs1428604100; called by mutect2, varscan2
- GTF3C1 | c.5833G>A p.G1945S | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as rs571876185, COSV62241501, COSV62241776; called by muse, mutect2, varscan2
- GTPBP1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 99/349 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99323175; called by muse, mutect2, varscan2
- GUF1 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs545503516, COSV54945907; called by mutect2, varscan2
- H4C2 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs1432646192; called by muse, mutect2
- HARS1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs769340873, COSV56907864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAS1 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 36/672 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs981832532, COSV55787257, COSV55787907; called by muse, mutect2
- HAUS3 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 22/411 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV54722118; called by muse, mutect2
- HCK | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 33/363 reads (9%) | catalogued as COSV52942353, COSV52943146; called by muse, mutect2
- HCN4 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 88/485 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs553950644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC4 | c.2423C>T p.T808M | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772980393, COSV100614458; called by muse, varscan2
- HEATR5B | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1264981851, COSV51849846; called by muse, mutect2, varscan2
- HECTD4 | c.8704C>T p.Q2902* | Nonsense Mutation (SNP) | VAF 31/457 reads (7%) | catalogued as COSV66394874; called by muse, mutect2
- HECTD4 | c.5558C>T p.A1853V | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs775749459; called by muse, varscan2
- HECW2 | c.3334A>G p.R1112G | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1482140882, COSV53657633; called by muse, mutect2, varscan2
- HECW2 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 134/521 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs781780695, COSV53653451; called by muse, mutect2, varscan2
- HERC2 | c.5282C>T p.P1761L | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs779293972; called by muse, mutect2, varscan2
- HGFAC | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs570074246, COSV100123380; called by muse, mutect2, varscan2
- HGH1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 128/700 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963312493; called by muse, varscan2
- HIP1 | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782712426, COSV61190764; called by muse, mutect2
- HIRA | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54273300; called by muse, mutect2, varscan2
- HIVEP3 | c.1601dup p.V535Cfs*26 | Frame Shift Ins (INS) | VAF 38/318 reads (12%) | catalogued as rs748174813; called by mutect2, varscan2
- HK2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs142756990; called by muse, mutect2, varscan2
- HLA-B | c.749A>G p.Q250R | Missense Mutation (SNP) | VAF 143/684 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101318292, COSV69522623; called by muse, mutect2, varscan2
- HOXA5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs780972209, COSV56072369; called by muse, mutect2, varscan2
- HOXB4 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 73/396 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1254723779; called by muse, mutect2, varscan2
- HOXD3 | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 100/610 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs761408179; called by muse, mutect2, varscan2
- HR | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 78/721 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372594532; called by muse, mutect2, varscan2
- HRNR | c.3449G>A p.R1150Q | Missense Mutation (SNP) | VAF 50/1344 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1345892407; called by muse, mutect2
- HUWE1 | c.10964G>A p.R3655Q | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs375143574, COSV99469870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HVCN1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs772902585, COSV54371866; called by muse, mutect2, varscan2
- ICAM2 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 89/398 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs368636050; called by muse, mutect2, varscan2
- ICAM2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 27/607 reads (4%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.852); catalogued as rs1254256952; called by muse, mutect2
- IFIT3 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 17/409 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1302459440; called by muse, mutect2
- IFT43 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs147933112; ClinVar: uncertain significance; called by muse, varscan2
- IGHMBP2 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs201563456, CM041023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV3-21 | c.199G>C p.V67L | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.154); catalogued as rs564713416; called by muse, varscan2
- IGHV3-21 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 88/535 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); catalogued as rs191067794; called by muse, mutect2, varscan2
- IL17C | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 154/678 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs377230543; called by muse, mutect2, varscan2
- IL18BP | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 150/641 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs200994634, COSV52622772; called by muse, mutect2, varscan2
- IMP3 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 41/696 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs911189380; called by muse, mutect2
- INF2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs1480273257, COSV57980000; called by muse, mutect2
- INF2 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 35/692 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV53029756; called by muse, mutect2
- INHBE | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as rs780594253; called by muse, mutect2, varscan2
- INPP4A | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403218618, COSV50791099; called by muse, mutect2, varscan2
- INPP4A | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 104/526 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.308); catalogued as rs372688727, COSV99303199; called by muse, mutect2, varscan2
- INSIG1 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs757412249; called by muse, varscan2
- INSYN2A | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 93/435 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1251294324, COSV54763623; called by muse, mutect2, varscan2
- INTS1 | c.5141G>A p.R1714H | Missense Mutation (SNP) | VAF 97/414 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs370729536; called by muse, mutect2, varscan2
- IP6K2 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 105/404 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs777041135, COSV99584016; called by muse, mutect2, varscan2
- IQCF5 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71306743; called by muse, mutect2
- ISL2 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV51958461; called by muse, mutect2
- ITFG1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 72/291 reads (25%) | catalogued as rs1189775420, COSV57744661; called by muse, mutect2, varscan2
- ITGA9 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1487643499, COSV99292639; called by muse, mutect2, varscan2
- ITIH4 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 109/470 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs572371573, COSV56575409; called by muse, mutect2, varscan2
- ITIH6 | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 117/448 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs779817369, COSV54487293; called by muse, mutect2, varscan2
- ITPRID1 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs142885665; called by muse, mutect2, varscan2
- IZUMO1R | c.410G>A p.R137H (on ENST00000440961; = p.R144H on NM_001199206.3) | Missense Mutation (SNP) | VAF 81/399 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs759451248, COSV60623414; called by muse, mutect2, varscan2
- JAG1 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as rs1251308431; called by muse, mutect2
- JKAMP | c.967A>G p.N323D (on ENST00000554271 / NM_001284201.1; = p.N309D on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.115); catalogued as rs888313868; called by muse, mutect2
- JMJD1C | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748501330, COSV67858357; called by muse, mutect2, varscan2
- JPH4 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 35/844 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1203115506; called by muse, mutect2
- KANSL1 | c.1061T>C p.L354S | Missense Mutation (SNP) | VAF 32/866 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV52267512; called by muse, mutect2
- KAT6A | c.5593C>T p.P1865S | Missense Mutation (SNP) | VAF 23/741 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.145); catalogued as rs948756413; called by muse, mutect2
- KAT6B | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs762613635, COSV54741726; called by muse, mutect2, varscan2
- KBTBD11 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs767953618; called by muse, mutect2, varscan2
- KCNA1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1053557642, COSV66836572; called by muse, mutect2, varscan2
- KCNC2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 28/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260222970, COSV54373037; called by muse, mutect2
- KCNF1 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 109/517 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54465464; called by muse, mutect2, varscan2
- KCNG1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 108/504 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as rs1001316061, COSV65368845; called by muse, mutect2, varscan2
- KCNH4 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs149532318, COSV52916599; called by muse, mutect2, varscan2
- KCNH7 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs770813344; called by muse, mutect2, varscan2
- KCNJ1 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.875); catalogued as rs1407978666; called by muse, mutect2, varscan2
- KCNK15 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 98/482 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.03); catalogued as rs1023780379, COSV104425718; called by muse, mutect2
- KCNK9 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as rs201337202, COSV57282477; called by muse, mutect2, varscan2
- KCNN4 | c.1243G>T p.G415W | Missense Mutation (SNP) | VAF 25/531 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV99486901; called by muse, mutect2
- KCNS2 | c.1385T>C p.M462T | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs892956498; called by muse, mutect2
- KCNT1 | c.3583C>T p.R1195C (on ENST00000488444; = p.R1200C on NM_020822.3) | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372028322, COSV99705674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD13 | c.421del p.R141Gfs*13 | Frame Shift Del (DEL) | VAF 93/392 reads (24%) | catalogued as rs766440565; called by mutect2, pindel, varscan2
- KDM4D | c.1174C>A p.R392S | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100624305; called by muse, varscan2
- KDM6B | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 113/504 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV54680034; called by muse, mutect2, varscan2
- KEAP1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 112/633 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.309); catalogued as rs780969499, COSV50279167; called by muse, mutect2, varscan2
- KHK | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452577405; called by muse, mutect2
- KIAA1109 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV104390167; called by muse, mutect2, varscan2
- KIAA1328 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.116); catalogued as COSV99693552; called by muse, mutect2, varscan2
- KIAA2013 | c.1316G>A p.C439Y | Missense Mutation (SNP) | VAF 105/543 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1003002266; called by muse, mutect2, varscan2
- KIF19 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 74/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs529788944, COSV63428855; called by muse, mutect2, varscan2
- KIF1C | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 37/632 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as COSV100297054; called by muse, mutect2
- KIF20B | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1363717002; called by muse, mutect2, varscan2
- KIF24 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 73/430 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs772997925, COSV100799239; called by muse, mutect2, varscan2
- KIF26B | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 51/784 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV101314281; called by muse, mutect2
- KIF26B | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 142/579 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771122784, COSV63636258; called by muse, mutect2, varscan2
- KIF2B | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs1165351887; called by muse, mutect2
- KIF6 | c.1452dup p.E485Rfs*16 | Frame Shift Ins (INS) | VAF 34/226 reads (15%) | catalogued as rs755810135; called by mutect2, varscan2
- KIF7 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs754486000, COSV67997360; called by muse, mutect2, varscan2
- KLF12 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.796); catalogued as rs375809451; called by muse, mutect2, varscan2
- KLHL21 | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 40/748 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs1226487856; called by muse, mutect2
- KLHL33 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 110/470 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs1473146853; called by muse, mutect2, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 44/218 reads (20%) | catalogued as rs1288106608; called by mutect2, varscan2
- KLK7 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV58344045; called by muse, mutect2
- KMT2A | c.6610C>T p.R2204W | Missense Mutation (SNP) | VAF 37/441 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs150570074; called by muse, mutect2
- KMT2A | c.11114G>A p.R3705H | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs907814598; called by muse, mutect2, varscan2
- KMT2B | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs898693925; called by muse, mutect2
- KMT2D | c.16273G>A p.E5425K | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM146878, COSV56454472; called by muse, varscan2
- KRT36 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 97/411 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748338517; called by muse, mutect2, varscan2
- KRT77 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs140276094; called by muse, mutect2, varscan2
- KRTAP13-1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 86/467 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs1235464301, COSV62663493; called by muse, mutect2, varscan2
- KRTAP20-2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 67/351 reads (19%) | PolyPhen benign (0.005); catalogued as rs144523386; called by muse, varscan2
- LAMA3 | c.5776G>A p.A1926T (on ENST00000313654 / NM_198129.4; = p.A317T on NM_000227.6) | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1172908329, COSV52536481; called by muse, mutect2
- LAMB3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 114/523 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1289411853; called by muse, mutect2, varscan2
- LARP6 | c.19del p.E7Rfs*86 | Frame Shift Del (DEL) | VAF 51/427 reads (12%) | catalogued as rs1403731513; called by mutect2, pindel, varscan2
- LBX1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929972; called by muse, mutect2, varscan2
- LDB2 | c.173T>G p.F58C | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58782917; called by muse, mutect2, varscan2
- LEFTY2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 122/490 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs757490152; called by muse, mutect2, varscan2
- LIG1 | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 82/475 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs780457620, COSV54390019, COSV99619310; called by muse, mutect2, varscan2
- LIM2 | c.319dup p.S107Ffs*59 (on ENST00000596399 / NM_001161748.2; = p.S149Ffs*59 on NM_030657.4) | Frame Shift Ins (INS) | VAF 58/227 reads (26%) | catalogued as rs1490674848; called by mutect2, varscan2
- LIME1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 44/820 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as rs1486527288; called by muse, mutect2
- LINGO3 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as rs1402279196; called by muse, varscan2
- LIPK | c.588dup p.A197Cfs*9 | Frame Shift Ins (INS) | VAF 56/309 reads (18%) | catalogued as rs776732749; called by mutect2*, pindel, varscan2
- LLGL1 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377439323; called by muse, mutect2, varscan2
- LMF1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 113/457 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754428234; called by muse, mutect2, varscan2
- LPCAT1 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs201807269; called by muse, mutect2, varscan2
- LPGAT1 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1447899407; called by muse, mutect2
- LPIN3 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs575986671; called by muse, mutect2, varscan2
- LRIT1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 153/565 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs1238128947, COSV100928085; called by muse, mutect2, varscan2
- LRIT1 | c.52dup p.Q18Pfs*19 | Frame Shift Ins (INS) | VAF 71/344 reads (21%) | catalogued as rs759958964; called by mutect2, varscan2
- LRIT2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199677093; called by muse, mutect2
- LRP1B | c.1806G>T p.E602D | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV67227021; called by muse, mutect2, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 24/400 reads (6%) | catalogued as COSV55542953; called by muse, mutect2
- LRRC4B | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.154); catalogued as rs757301098, COSV66753408; called by muse, varscan2
- LRRC53 | c.2422del p.L808Cfs*9 | Frame Shift Del (DEL) | VAF 76/366 reads (21%) | catalogued as rs1011562092; called by mutect2, pindel, varscan2
- LRRC71 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs752271297; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470dup p.R491Tfs*14 | Frame Shift Ins (INS) | VAF 44/196 reads (22%) | catalogued as rs779699744; called by mutect2, varscan2
- LRRK2 | c.4448G>A p.R1483Q | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs113431708, CM081327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRSAM1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138715791; called by muse, mutect2, varscan2
- LRTM1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV55543868; called by muse, varscan2
- LSMEM1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs143265336; called by muse, mutect2, varscan2
- LYN | c.1468T>C p.F490L | Missense Mutation (SNP) | VAF 31/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101571254; called by muse, mutect2
- LZTS1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 44/519 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs757004740, COSV56117288; called by muse, mutect2
- LZTS2 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 124/526 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs775223021, COSV64651708, COSV64653128; called by muse, mutect2, varscan2
- MACF1 | c.19886A>G p.D6629G (on ENST00000372915; = p.D4674G on NM_012090.5) | Missense Mutation (SNP) | VAF 34/406 reads (8%) | catalogued as COSV57109858; called by muse, mutect2
- MAGEL2 | c.1745G>A p.C582Y | Missense Mutation (SNP) | VAF 37/684 reads (5%) | SIFT deleterious, low confidence (0); catalogued as rs1375018072; called by muse, mutect2
- MAML3 | c.1956_1958dup p.P654dup | In Frame Ins (INS) | VAF 73/441 reads (17%) | catalogued as rs777873701; called by pindel, varscan2
- MAOB | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770711084; called by muse, mutect2, varscan2
- MAP1S | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 106/510 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100141042, COSV60721482; called by muse, mutect2, varscan2
- MAP3K10 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767896869, COSV53422714; called by muse, mutect2, varscan2
- MAP3K12 | c.2323G>A p.V775I | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.935); catalogued as rs200504418; called by muse, mutect2
- MAP3K19 | c.2161del p.T721Hfs*3 | Frame Shift Del (DEL) | VAF 46/322 reads (14%) | catalogued as rs771955948; called by mutect2, varscan2
- MAP4K4 | c.1628A>T p.Q543L (on ENST00000347699 / NM_001242559.2; = p.Q512L on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as rs1308849887; called by muse, mutect2
- MAPK1IP1L | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 31/607 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1190500765; called by muse, mutect2
- MARCHF1 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 18/274 reads (7%) | catalogued as rs867253866; called by muse, mutect2
- MARCHF4 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 122/500 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1214830803, COSV56102656; called by muse, mutect2, varscan2
- MARK4 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 33/519 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1447493288, COSV53469463, COSV53469675; called by muse, mutect2
- MBD6 | c.2012dup p.T672Yfs*45 | Frame Shift Ins (INS) | VAF 27/138 reads (20%) | catalogued as rs750430563; called by mutect2, varscan2
- MBNL3 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 67/416 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100898499; called by muse, mutect2, varscan2
- MCM4 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 68/535 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs144766420; called by muse, mutect2, varscan2
- MCM9 | c.3218C>G p.S1073C | Missense Mutation (SNP) | VAF 29/512 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV100309636; called by muse, mutect2
- MCRIP1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 89/412 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.799); catalogued as rs1390770201; called by muse, mutect2, varscan2
- MCTP1 | c.2137T>C p.S713P | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as rs1353763415, COSV56502604; called by muse, mutect2
- MDGA2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 106/628 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1335912769; called by muse, varscan2
- MDN1 | c.11812del p.L3938* | Frame Shift Del (DEL) | VAF 34/335 reads (10%) | catalogued as COSV101021293, COSV65516344; called by mutect2, pindel, varscan2
- MED13L | c.2999A>G p.N1000S | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as rs949240808; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 134/568 reads (24%) | catalogued as rs745558596; called by mutect2, varscan2
- MEST | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1554435549, COSV99784188; called by muse, mutect2, varscan2
- METTL25 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs745443693; called by muse, mutect2, varscan2
- MFGE8 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150914740; called by muse, mutect2, varscan2
- MGAM2 | c.4391G>A p.R1464H | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750483353, COSV72176380; called by muse, mutect2
- MGME1 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs756800070; called by muse, mutect2, varscan2
- MIB2 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.857); catalogued as rs367615032; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 104/489 reads (21%) | catalogued as rs762448666; called by pindel, varscan2
- MIDN | c.1301del p.G434Afs*91 | Frame Shift Del (DEL) | VAF 134/524 reads (26%) | catalogued as COSV56294193; called by mutect2, varscan2
- MIGA2 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 122/517 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376127108; called by muse, mutect2, varscan2
- MINAR1 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as rs1310628023; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 90/364 reads (25%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MLNR | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 78/523 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201815723, COSV54534818; called by muse, mutect2, varscan2
- MLST8 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs770435531; called by muse, mutect2, varscan2
- MMP15 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 23/634 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as rs1197108615; called by muse, mutect2
- MMP28 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 107/400 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs1000026322; called by muse, mutect2, varscan2
- MMUT | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1369724342; called by muse, mutect2, varscan2
- MORC2 | c.1823G>A p.R608H (on ENST00000397641 / NM_001303256.3; = p.R546H on NM_014941.3) | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs781443418, COSV53199396; called by muse, mutect2, varscan2
- MOS | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 52/628 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs552123421; called by muse, mutect2
- MPV17L2 | c.493dup p.Q165Pfs*175 | Frame Shift Ins (INS) | VAF 48/276 reads (17%) | catalogued as rs746591385; called by mutect2, varscan2
- MROH1 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs1290394683; called by muse, mutect2, varscan2
- MRTFB | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 72/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776453451; called by muse, mutect2, varscan2
- MST1R | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 28/644 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV56569944; called by muse, mutect2
- MT1A | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1201317627; called by muse, mutect2, varscan2
- MTHFD2L | c.1033dup p.I345Nfs*10 (on ENST00000395759 / NM_001144978.2; = p.I287Nfs*10 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 46/210 reads (22%) | catalogued as rs761538540; called by mutect2, varscan2
- MTHFSD | c.1003C>T p.R335W (on ENST00000360900 / NM_001159377.2; = p.R334W on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/549 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747084274; called by muse, mutect2, varscan2
- MTMR3 | c.1855A>G p.T619A | Missense Mutation (SNP) | VAF 25/410 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs971207049; called by muse, mutect2
- MTMR4 | c.2582A>G p.E861G | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.057); catalogued as rs1567927102; called by muse, mutect2
- MTNR1B | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 29/547 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.151); catalogued as rs1177579394; called by muse, mutect2
- MTNR1B | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 84/432 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369557205; called by muse, varscan2
- MUC4 | c.13063C>T p.R4355C (on ENST00000463781 / NM_018406.7; = p.R119C on NM_004532.6) | Missense Mutation (SNP) | VAF 19/415 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs770422854, COSV57777523; called by muse, mutect2
- MUC4 | c.7295G>A p.R2432H | Missense Mutation (SNP) | VAF 144/1604 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); catalogued as rs879118476, COSV62148705, COSV62198780; called by muse, mutect2
- MX2 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.037); catalogued as COSV58094963; called by muse, mutect2
- MYBPC2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as rs760296908, COSV63100575; called by muse, mutect2, varscan2
- MYCBPAP | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 211/422 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs762195247, COSV100088026; called by muse, mutect2, varscan2
- MYCN | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV99808578; called by muse, mutect2
- MYF6 | c.522T>C p.L174= | Splice Region (SNP) | VAF 65/255 reads (25%) | catalogued as rs1043623666; called by muse, mutect2, varscan2
- MYH10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs777205800, COSV52603274; called by muse, varscan2
- MYH9 | c.5317G>A p.A1773T | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs190450967; called by muse, mutect2
- MYO15A | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 134/549 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs757367598; called by muse, mutect2, varscan2
- MYO18B | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 116/449 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs768072435, COSV59130698; called by muse, mutect2, varscan2
- MYOD1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 21/578 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384940737, COSV100000125; called by muse, mutect2
- NAA11 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 88/460 reads (19%) | catalogued as rs957566798, COSV54513781; called by muse, mutect2, varscan2
- NAALADL1 | c.2162G>T p.S721I | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1313479234; called by muse, mutect2
- NAALADL2 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV101380550; called by muse, mutect2
- NBEAL1 | c.3931dup p.T1311Nfs*3 | Frame Shift Ins (INS) | VAF 60/296 reads (20%) | catalogued as rs1266749768; called by mutect2, pindel, varscan2
- NCBP3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50107225; called by muse, mutect2
- NCK2 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs1411771322, COSV51892218; called by muse, mutect2, varscan2
- NCKAP5 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs765464937; called by muse, mutect2, varscan2
- NCOR2 | c.5470G>A p.A1824T | Missense Mutation (SNP) | VAF 65/455 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs767181136, COSV100657163; called by muse, mutect2, varscan2
- NDUFA4L2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202089444; called by muse, mutect2, varscan2
- NEFL | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 120/561 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.953); catalogued as COSV55336970; called by muse, mutect2, varscan2
- NEFL | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 57/507 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs1432127004, COSV55338367; called by muse, mutect2, varscan2
- NETO1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100199307; called by muse, mutect2
- NEUROD1 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 119/526 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99716725; called by muse, mutect2, varscan2
- NFATC1 | c.949A>G p.N317D | Missense Mutation (SNP) | VAF 41/583 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1464778587; called by muse, mutect2
- NFATC2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 24/442 reads (5%) | catalogued as rs1305798984, COSV65360308; called by muse, mutect2
- NGRN | c.584_585del p.E195Vfs*17 | Frame Shift Del (DEL) | VAF 82/381 reads (22%) | catalogued as rs778554885; called by pindel, varscan2
- NKD1 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 42/672 reads (6%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.912); catalogued as COSV51690114; called by muse, mutect2
- NKRF | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs1228739613; called by muse, mutect2
- NKX2-4 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 160/690 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs977074895; called by muse, varscan2
- NLGN1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV64325767; called by muse, mutect2
- NLRP11 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 68/280 reads (24%) | catalogued as COSV64086909; called by muse, mutect2, varscan2
- NLRP12 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs1488544336; called by muse, mutect2
- NOG | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 108/461 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240543; called by muse, mutect2, varscan2
- NOL6 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 29/411 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV53040365; called by muse, mutect2
- NOMO1 | c.2872C>T p.R958* | Nonsense Mutation (SNP) | VAF 34/212 reads (16%) | catalogued as rs919783596; called by muse, mutect2, varscan2
- NPEPL1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 109/487 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs765937608; called by muse, mutect2, varscan2
- NPFFR2 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV58146263; called by muse, mutect2
- NR4A2 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); catalogued as rs1553455972; called by muse, mutect2
- NRAP | c.3829C>T p.R1277C (on ENST00000359988 / NM_001322945.2; = p.R1242C on NM_006175.4) | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1452260134, COSV63488817; called by muse, mutect2
- NRDC | c.616dup p.T206Nfs*3 | Frame Shift Ins (INS) | VAF 31/182 reads (17%) | catalogued as rs747283256; called by mutect2, varscan2
- NRP2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55933086; called by muse, varscan2
- NRSN2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 113/550 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); catalogued as rs367945601; called by muse, mutect2, varscan2
- NSUN7 | c.1834del p.H612Ifs*8 | Frame Shift Del (DEL) | VAF 136/576 reads (24%) | catalogued as rs1560567993; called by mutect2, pindel, varscan2
- NT5C2 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs1030219633, COSV58414921; called by muse, mutect2, varscan2
- NTNG1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53977286; called by muse, mutect2
- NUP210L | c.1594A>G p.N532D | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1346802892; called by muse, mutect2
- NUP214 | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 54/242 reads (22%) | catalogued as COSV63910643; called by mutect2, varscan2
- OPCML | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs770676127, COSV59435220; called by muse, mutect2, varscan2
- OR13F1 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV58251387; called by muse, mutect2
- OR14C36 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs750630667; called by muse, mutect2
- OR4K14 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs532165188, COSV100520536; called by muse, mutect2, varscan2
- OR4K3 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1304463754; called by muse, mutect2
- OR51A4 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs763198309, COSV66748968; called by muse, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 82/409 reads (20%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 33/169 reads (20%) | catalogued as rs1254479213; called by mutect2, pindel, varscan2
- OR5B21 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 114/496 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.323); catalogued as rs1565175880; called by muse, mutect2, varscan2
- OR5P3 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1351783142, COSV60429462; called by muse, mutect2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 43/308 reads (14%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR6K3 | c.884T>C p.V295A (on ENST00000368146; = p.V279A on NM_001005327.2) | Missense Mutation (SNP) | VAF 27/426 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1558014291; called by muse, mutect2
- OR6V1 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 35/632 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.177); catalogued as rs745694740; called by muse, mutect2
- OR7D4 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58071600; called by muse, mutect2
- OSBPL5 | c.2276A>G p.Q759R | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1454276425; called by muse, mutect2, varscan2
- OSBPL5 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 77/391 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs774617578; called by muse, mutect2, varscan2
- OSCAR | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 38/714 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757218082; called by muse, mutect2
- OSM | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53161359; called by muse, mutect2, varscan2
- OSR2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 75/387 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as rs1315140862, COSV52556029; called by muse, mutect2, varscan2
- OTOF | c.2281C>T p.R761W (on ENST00000272371 / NM_194248.3; = p.R14W on NM_004802.4) | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs137982529, COSV55508691, COSV55511066; called by muse, mutect2, varscan2
- OTUD7A | c.853C>T p.P285S (on ENST00000307050 / NM_001382637.1; = p.P278S on NM_130901.3) | Missense Mutation (SNP) | VAF 27/472 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1192790812; called by muse, mutect2
- OXSM | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 104/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55002716; called by muse, mutect2, varscan2
- P3H3 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377494942; called by muse, mutect2
- PAFAH2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs200427118; called by muse, mutect2, varscan2
- PALM | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs1025992571; called by muse, mutect2, varscan2
- PALM | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 132/564 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as rs780220977, COSV52766723; called by muse, mutect2, varscan2
- PANK4 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 36/582 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65867797; called by muse, mutect2
- PAQR8 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 101/472 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62441956; called by muse, mutect2, varscan2
- PARD3 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs778567435; called by muse, mutect2, varscan2
- PAX1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs764757880; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 65/238 reads (27%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.3676A>G p.M1226V (on ENST00000296302 / NM_001366071.2; = p.M1201V on NM_018313.5) | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV56308586; called by muse, mutect2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 32/164 reads (20%) | catalogued as rs771618422; called by pindel, varscan2
- PCDH1 | c.3115G>A p.V1039I | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs554581630; called by muse, mutect2, varscan2
- PCDH1 | c.1363_1365del p.K455del | In Frame Del (DEL) | VAF 76/444 reads (17%) | catalogued as rs751752911; called by pindel, varscan2
- PCDH11X | c.1978A>G p.T660A | Missense Mutation (SNP) | VAF 20/413 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53499345; called by muse, mutect2
- PCDH11X | c.3712G>T p.A1238S | Missense Mutation (SNP) | VAF 98/556 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV53464812; called by muse, mutect2, varscan2
- PCDH18 | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 21/462 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61266383; called by muse, mutect2
- PCDH19 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 72/535 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55261394; called by muse, mutect2, varscan2
- PCDH7 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 141/617 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV62337257; called by muse, mutect2, varscan2
- PCDHA13 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 20/324 reads (6%) | catalogued as rs782007101, COSV56489683; called by muse, mutect2
- PCDHA13 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs782791774, COSV56485031, COSV56509935; called by muse, mutect2, varscan2
- PCDHA2 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100973875; called by muse, mutect2, varscan2
- PCDHA6 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 115/540 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV65359015; called by muse, mutect2, varscan2
- PCDHB11 | c.2246A>G p.Y749C | Missense Mutation (SNP) | VAF 27/531 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554285794; called by muse, mutect2
- PCDHGA6 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99534015; called by muse, mutect2
- PCNX2 | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.609); catalogued as COSV50818597; called by muse, mutect2
- PCSK1 | c.1103C>A p.A368D | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100226736; called by muse, mutect2, varscan2
- PDE3B | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99963011; called by muse, mutect2
- PDE4A | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as rs1234243707; called by muse, mutect2, varscan2
- PDE6A | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768596256, COSV54926143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFB | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 17/407 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); catalogued as rs1237058477, COSV100483586; called by muse, mutect2
- PDIA4 | c.1639G>A p.V547I (on ENST00000286091 / NM_001371244.1; = p.V546I on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/465 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs749231315, COSV104376076; called by muse, mutect2, varscan2
- PDZK1IP1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 77/380 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as rs370702290; called by muse, mutect2, varscan2
- PEPD | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 46/802 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99728637; called by muse, mutect2
- PGC | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs774401575; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 68/360 reads (19%) | catalogued as rs748850271; called by pindel, varscan2
- PHLDA1 | c.1104_1109del p.P374_H375del | In Frame Del (DEL) | VAF 93/648 reads (14%) | catalogued as rs750164236; called by mutect2, pindel, varscan2
- PHRF1 | c.4304C>T p.A1435V (on ENST00000264555 / NM_001286581.2; = p.A1434V on NM_020901.4) | Missense Mutation (SNP) | VAF 55/446 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs770253426; called by muse, mutect2, varscan2
- PHYHIP | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 36/696 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as rs1407268678; called by muse, mutect2
- PID1 | c.692G>A p.R231Q (on ENST00000354069 / NM_001330156.1; = p.R229Q on NM_017933.5) | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs764261003, COSV62474106; called by muse, mutect2, varscan2
- PIEZO2 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1323885459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIF1 | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 119/445 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV51422964; called by muse, mutect2, varscan2
- PIK3C2G | c.2069C>A p.P690Q (on ENST00000676171; = p.P649Q on NM_004570.5) | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.945); catalogued as COSV56808065; called by muse, mutect2
- PIK3C3 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs1424653423; called by muse, mutect2, varscan2
- PIK3C3 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs766344105, COSV56281784; called by muse, varscan2
- PIK3CG | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs554272230, COSV63247299; called by muse, mutect2, varscan2
- PIKFYVE | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs779881345, COSV52243181; called by muse, mutect2, varscan2
- PINK1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 96/376 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs202128685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIP5K1C | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 111/540 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs763799116, COSV58952873; called by muse, mutect2, varscan2
- PKD1 | c.12683G>A p.R4228Q (on ENST00000262304 / NM_001009944.3; = p.R4227Q on NM_000296.4) | Missense Mutation (SNP) | VAF 43/636 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs1064797205; called by muse, mutect2
- PLA2G2F | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs370472527; called by muse, mutect2, varscan2
- PLCB2 | c.1957G>A p.G653S | Missense Mutation (SNP) | VAF 105/445 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636014, COSV53036310; called by muse, mutect2, varscan2
- PLEC | c.9046C>A p.L3016M (on ENST00000322810 / NM_201380.4; = p.L2906M on NM_000445.5) | Missense Mutation (SNP) | VAF 78/721 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs563493425; called by muse, mutect2, varscan2
- PLEC | c.5245C>T p.R1749W (on ENST00000322810 / NM_201380.4; = p.R1639W on NM_000445.5) | Missense Mutation (SNP) | VAF 88/766 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs782551115, COSV59602296; ClinVar: uncertain significance; called by muse, varscan2
- PLEC | c.4529G>A p.R1510Q (on ENST00000322810 / NM_201380.4; = p.R1400Q on NM_000445.5) | Missense Mutation (SNP) | VAF 92/737 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs782128071; called by muse, varscan2
- PLEC | c.1882C>T p.R628W (on ENST00000322810 / NM_201380.4; = p.R518W on NM_000445.5) | Missense Mutation (SNP) | VAF 77/595 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs201001882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA6 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs771460879; called by muse, varscan2
- PLEKHM3 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 85/393 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.845); catalogued as rs770640067; called by muse, mutect2, varscan2
- PLXNA3 | c.3040G>A p.G1014R | Missense Mutation (SNP) | VAF 72/568 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.676); catalogued as rs1557207273, COSV63755857; called by muse, mutect2, varscan2
- PNKD | c.43dup p.A15Gfs*17 | Frame Shift Ins (INS) | VAF 97/557 reads (17%) | catalogued as rs777779692; called by mutect2, pindel, varscan2
- PNLIPRP2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.376); catalogued as COSV53943363; called by muse, mutect2
- PNPLA6 | c.1255G>A p.V419I (on ENST00000414982 / NM_001166111.2; = p.V371I on NM_006702.5) | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369465821; ClinVar: uncertain significance; called by muse, mutect2
- PNPLA7 | c.3323G>A p.S1108N | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257442392; called by muse, mutect2
- POGK | c.689del p.N230Tfs*8 | Frame Shift Del (DEL) | VAF 88/441 reads (20%) | catalogued as COSV63312096; called by mutect2, pindel, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 56/208 reads (27%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLDIP2 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs953769946; called by muse, mutect2
- POLE3 | c.322_324del p.K108del | In Frame Del (DEL) | VAF 68/255 reads (27%) | catalogued as rs760361084; called by pindel, varscan2
- POLL | c.1066-1G>T p.X356_splice | Splice Site (SNP) | VAF 132/530 reads (25%) | catalogued as COSV100150183; called by muse, mutect2, varscan2
- POLR3F | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 93/415 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.113); catalogued as rs1477436669; called by muse, mutect2, varscan2
- POLRMT | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 167/651 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751158506; called by muse, mutect2, varscan2
- POMC | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 112/504 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs28932471; called by muse, varscan2
- POR | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 23/531 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.098); catalogued as rs782539859; called by muse, mutect2
- POTEF | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 30/626 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62544059; called by muse, mutect2
- POTEH | c.444del p.S149Afs*55 | Frame Shift Del (DEL) | VAF 120/400 reads (30%) | catalogued as COSV100625199, COSV100625241, COSV58885178; called by pindel, varscan2
- POTEI | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 98/583 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); catalogued as rs778956132; called by muse, mutect2, varscan2
- POU3F1 | c.770A>C p.Q257P | Missense Mutation (SNP) | VAF 137/622 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1416148294; called by muse, mutect2, varscan2
- POU3F3 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 67/325 reads (21%) | catalogued as rs1558702991; called by mutect2, pindel, varscan2
- POU4F2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 119/569 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753645099; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2059A>G p.M687V | Missense Mutation (SNP) | VAF 149/595 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV53452703; called by muse, mutect2, varscan2
- PPARG | c.154G>A p.V52I (on ENST00000287820 / NM_015869.5; = p.V22I on NM_005037.7) | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as rs149324518; called by muse, mutect2, varscan2
- PPEF2 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs186986454, COSV99714455; called by muse, mutect2, varscan2
- PPP6R2 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 132/521 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs781759770; called by muse, mutect2, varscan2
- PRDM15 | c.2425G>A p.V809I | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs746926665, COSV54149574; called by muse, mutect2, varscan2
- PRDM9 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 103/509 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99689794; called by muse, mutect2, varscan2
- PRELID3A | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV61254453; called by muse, mutect2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 53/380 reads (14%) | catalogued as rs764112302; called by mutect2, varscan2
- PREX2 | c.2539A>G p.S847G | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV99904746; called by muse, mutect2
- PRICKLE3 | c.688T>C p.Y230H | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557100495; called by muse, mutect2, varscan2
3,177 further variants in this file (2,038 protein-altering or splice-affecting, 990 silent, 149 other) are not listed here.
